Somatic mutation profile of tumor specimen TCGA-55-5899-01A (aliquot TCGA-55-5899-01A-11D-1625-08) from TCGA case TCGA-55-5899, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung.
Specimen TCGA-55-5899-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 683228c7-dcd6-430f-88f5-a1afeacb5ffe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-5899-10A (Blood Derived Normal), aliquot TCGA-55-5899-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd5b1acd-5149-4251-829d-111dbcbc1111

The open-access MAF lists 485 somatic variants for this specimen: 359 protein-altering or splice-affecting, 116 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 318, Silent 116, Nonsense Mutation 22, Frame Shift Del 8, Splice Site 6, RNA 6, Frame Shift Ins 2, Translation Start Site 2, Intron 2, 5'UTR 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EYA1 | c.1531A>T p.K511* | Nonsense Mutation (SNP) | VAF 26/120 reads (22%) | catalogued as rs1057520766, COSV100380082, COSV58169184; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC25A15 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759454598, COSV58557664; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455del p.P152Rfs*18 | Frame Shift Del (DEL) | VAF 27/68 reads (40%) | catalogued as rs730882019, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by mutect2*, pindel, varscan2*
- ACKR1 | c.917T>A p.L306Q | Missense Mutation (SNP) | VAF 162/416 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV63673908, COSV63674549; called by muse, varscan2
- ADAM33 | c.1981G>T p.G661W | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62936113; called by muse, mutect2, varscan2
- ADAMTS12 | c.1064A>T p.N355I | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61271989; called by muse, mutect2, varscan2
- ADAMTS17 | c.2086G>T p.G696C | Missense Mutation (SNP) | VAF 88/134 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51488431, COSV99170605; called by muse, mutect2, varscan2
- ADCY8 | c.2645T>C p.L882P | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.51); catalogued as COSV53919154; called by muse, mutect2, varscan2
- ADD2 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV52463178, COSV52466789; called by muse, mutect2, varscan2
- ADH1A | c.260-2A>T p.X87_splice | Splice Site (SNP) | VAF 23/42 reads (55%) | catalogued as COSV52925754; called by muse, mutect2
- ADH1C | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 100/488 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs1177587007, COSV72463577; called by muse, mutect2, varscan2
- ALG10 | c.704A>T p.Q235L | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56793575; called by muse, mutect2, varscan2
- ALKBH8 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99509202; called by muse, mutect2
- ANKRD29 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52427077; called by muse, mutect2, varscan2
- ANKRD53 | c.629A>G p.N210S | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.259); catalogued as rs367980380; called by muse, mutect2, varscan2
- ANO2 | c.2769G>T p.M923I (on ENST00000356134 / NM_001278597.3; = p.M927I on NM_001278596.3) | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1226914943, COSV59035121; called by muse, mutect2, varscan2
- AOX1 | c.3241C>A p.P1081T | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV53496725; called by muse, mutect2, varscan2
- APC | c.2413del p.R805Dfs*15 | Frame Shift Del (DEL) | VAF 37/69 reads (54%) | catalogued as CM960067, COSV57322578; called by mutect2, pindel, varscan2
- APCDD1L | c.693G>T p.R231S | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV64487445; called by muse, mutect2, varscan2
- ARAP2 | c.2953G>T p.A985S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as COSV58289940; called by muse, mutect2, varscan2
- ARHGAP36 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs780684919, COSV52269902; called by muse, mutect2
- ARL6IP1 | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV58614729; called by muse, mutect2, varscan2
- ASPM | c.7865A>T p.Q2622L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.459); catalogued as COSV54134831; called by muse, mutect2, varscan2
- ASPM | c.1858G>C p.V620L | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV54134841; called by muse, mutect2, varscan2
- ASRGL1 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57125803; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2312G>A p.G771E (on ENST00000343619 / NM_001378531.1; = p.G765E on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/227 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52876466; called by muse, mutect2, varscan2
- B3GNT4 | c.1126C>A p.P376T | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); catalogued as rs1162646107; called by muse, mutect2
- BBS9 | c.2107T>A p.Y703N (on ENST00000242067 / NM_001348036.1; = p.Y663N on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54179201; called by muse, mutect2, varscan2
- BRDT | c.858G>T p.K286N | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62864021, COSV62864626; called by muse, mutect2, varscan2
- BRS3 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101036441, COSV65711204; called by muse, mutect2, varscan2
- BUB1B | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV55014551, COSV55015125; called by muse, mutect2, varscan2
- C22orf31 | c.835G>C p.V279L | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.006); catalogued as COSV99326520; called by muse, mutect2, varscan2
- C9orf131 | c.2392C>A p.P798T | Missense Mutation (SNP) | VAF 190/264 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as COSV56612830; called by muse, mutect2, varscan2
- CA10 | c.649C>A p.L217I | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.34); catalogued as COSV53362497; called by muse, mutect2, varscan2
- CABIN1 | c.4453G>A p.D1485N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV54086458; called by muse, mutect2, varscan2
- CACNA2D1 | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV62387131; called by muse, mutect2, varscan2
- CALB2 | c.467C>A p.T156N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100226433; called by muse, mutect2, varscan2
- CAMSAP1 | c.3667G>A p.V1223M | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs920214173, COSV56725564; called by muse, mutect2, varscan2
- CAPN6 | c.1663C>A p.Q555K | Missense Mutation (SNP) | VAF 92/105 reads (88%) | SIFT tolerated (0.36); PolyPhen benign (0.038); catalogued as COSV60696278; called by muse, mutect2, varscan2
- CARD11 | c.1519-1G>A p.X507_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | catalogued as COSV62756411; called by muse, mutect2, varscan2
- CARD6 | c.2112G>T p.E704D | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV54567859; called by muse, mutect2, varscan2
- CCDC171 | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 72/103 reads (70%) | catalogued as COSV52634529, COSV52648205; called by muse, mutect2, varscan2
- CCDC178 | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); catalogued as COSV55787329; called by muse, mutect2
- CCDC73 | c.1095A>T p.L365F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV58802153; called by muse, mutect2, varscan2
- CCKBR | c.791G>C p.R264P | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV58103811; called by muse, mutect2, varscan2
- CCNB3 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.537); catalogued as COSV52077507; called by muse, mutect2, varscan2
- CCT4 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as rs201252758, COSV66701837; called by muse, mutect2
- CD180 | c.1565T>G p.M522R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV56519212; called by muse, mutect2, varscan2
- CD226 | c.404C>A p.P135Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as COSV99710850; called by mutect2, varscan2
- CD38 | c.524A>G p.D175G | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.179); catalogued as COSV56891985; called by muse, mutect2, varscan2
- CDH6 | c.410G>T p.R137I | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV54075043; called by muse, mutect2, varscan2
- CDH6 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as rs1253119234, COSV54075068; called by muse, mutect2, varscan2
- CDX4 | c.544G>C p.D182H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65171811; called by muse, mutect2, varscan2
- CFAP47 | c.1864G>T p.A622S | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.166); catalogued as COSV99935855; called by muse, mutect2, varscan2
- CFHR5 | c.404C>A p.S135Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56825563; called by muse, mutect2, varscan2
- CHD6 | c.3217A>T p.S1073C | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58560162; called by muse, mutect2, varscan2
- CHD7 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV71113120; called by muse, mutect2, varscan2
- CHL1 | c.1736C>A p.S579Y (on ENST00000397491 / NM_001253387.1; = p.S595Y on NM_006614.4) | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.118); catalogued as COSV56600246; called by muse, mutect2, varscan2
- CHRNA7 | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0.047); catalogued as COSV60970999, COSV60973740; called by mutect2, varscan2
- CLINT1 | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51627243; called by muse, mutect2, varscan2
- CNST | c.1575G>T p.E525D | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as COSV63622212; called by muse, mutect2, varscan2
- CNTN3 | c.1105G>T p.G369C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55179654; called by muse, mutect2, varscan2
- COL24A1 | c.1762G>A p.G588R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65310474; called by muse, mutect2, varscan2
- COL4A5 | c.856G>T p.G286C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754975157, COSV60367381; called by muse, mutect2, varscan2
- COLGALT2 | c.1132G>T p.G378* | Nonsense Mutation (SNP) | VAF 55/230 reads (24%) | catalogued as COSV62299237, COSV62300117; called by muse, mutect2, varscan2
- CPA1 | c.518G>C p.W173S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50572881; called by muse, mutect2, varscan2
- CPSF2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.862); catalogued as rs1350880939, COSV54099575; called by muse, mutect2, varscan2
- CRACD | c.252G>T p.Q84H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV51727453; called by muse, mutect2, varscan2
- CSMD3 | c.11055C>A p.N3685K (on ENST00000297405 / NM_001363185.1; = p.N3516K on NM_052900.3) | Missense Mutation (SNP) | VAF 88/203 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV52132235, COSV52260743; called by muse, mutect2, varscan2
- CSMD3 | c.5579C>A p.A1860D (on ENST00000297405 / NM_001363185.1; = p.A1756D on NM_052900.3) | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV52137596, COSV52260763, COSV52313785; called by muse, mutect2, varscan2
- CSMD3 | c.5189G>T p.G1730V (on ENST00000297405 / NM_001363185.1; = p.G1626V on NM_052900.3) | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52260783; called by muse, mutect2, varscan2
- CSMD3 | c.1048C>G p.H350D | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV52260811; called by muse, mutect2, varscan2
- CSMD3 | c.427C>G p.P143A | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.133); catalogued as COSV52198600, COSV52260826; called by muse, mutect2, varscan2
- CST11 | c.18G>T p.W6C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as rs1428821269, COSV100776875, COSV63140095; called by muse, mutect2
- CST2 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.57); PolyPhen benign (0.05); catalogued as rs148108132, COSV59031524; called by muse, mutect2, varscan2
- DGKI | c.2563C>A p.P855T | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV55965863; called by muse, mutect2, varscan2
- DGKI | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1014496227, COSV55965895, COSV99932667; called by muse, mutect2, varscan2
- DHX15 | c.2199G>A p.W733* | Nonsense Mutation (SNP) | VAF 39/71 reads (55%) | catalogued as COSV61028475; called by muse, mutect2, varscan2
- DIP2A | c.1772C>A p.S591Y | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV100596342; called by muse, mutect2, varscan2
- DIP2A | c.3032G>T p.G1011V | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100596346; called by muse, mutect2, varscan2
- DIS3 | c.1031G>C p.R344T | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV100899871, COSV66707448; called by muse, mutect2, varscan2
- DPEP2 | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs368802189; called by muse, mutect2, varscan2
- DPEP3 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV52052246; called by muse, mutect2, varscan2
- DPEP3 | c.173C>A p.P58Q | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.123); catalogued as rs138005567, COSV99262887; called by muse, mutect2, varscan2
- DPP4 | c.1360T>A p.C454S | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62108564; called by muse, mutect2, varscan2
- DSE | c.327G>T p.L109F | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV59066435; called by muse, mutect2, varscan2
- DUSP14 | c.56T>C p.I19T | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1194285065; called by muse, mutect2
- DYNC2LI1 | c.470G>C p.R157T | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.076); catalogued as COSV53184522; called by muse, mutect2, varscan2
- EBF2 | c.746C>G p.S249W | Missense Mutation (SNP) | VAF 50/71 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68776774, COSV68779417; called by muse, mutect2, varscan2
- ELANE | c.467G>T p.W156L | Missense Mutation (SNP) | VAF 61/80 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55049106; called by muse, mutect2, varscan2
- ENOX1 | c.1561G>T p.G521C | Missense Mutation (SNP) | VAF 88/128 reads (69%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as COSV54910021; called by muse, mutect2, varscan2
- EPHB1 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 76/113 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101212900, COSV67662807, COSV67667023; called by muse, mutect2, varscan2
- ERBB3 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as rs1364442803, COSV57246357, COSV57259234; called by muse, mutect2, varscan2
- EVX2 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.123); catalogued as rs780971594, COSV57964510; called by muse, mutect2, varscan2
- FAM120AOS | c.311C>A p.P104H | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as COSV52908421; called by muse, mutect2, varscan2
- FAM209B | c.68C>G p.S23C | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100991027, COSV64915378; called by muse, mutect2, varscan2
- FAM71F1 | c.434G>T p.R145M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV59374453; called by muse, mutect2
- FAT4 | c.5470G>T p.D1824Y | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58699661; called by muse, mutect2, varscan2
- FBXL7 | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV100310366, COSV61650035; called by muse, mutect2, varscan2
- FBXO25 | c.517C>G p.L173V (on ENST00000382824 / NM_183421.2; = p.L106V on NM_012173.3) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV52338226; called by muse, mutect2, varscan2
- FGD5 | c.1528C>A p.P510T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs778355567, COSV53248198; called by muse, mutect2
- FGF1 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100532502; called by muse, mutect2, varscan2
- FKBP14 | c.197+1G>T p.X66_splice | Splice Site (SNP) | VAF 47/195 reads (24%) | catalogued as COSV99322254; called by muse, mutect2, varscan2
- FLG | c.10720G>T p.G3574C | Missense Mutation (SNP) | VAF 95/437 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64245448; called by muse, mutect2, varscan2
- FLG | c.2714G>T p.G905V | Missense Mutation (SNP) | VAF 207/540 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.366); catalogued as COSV64245453; called by muse, mutect2, varscan2
- FLG2 | c.79A>C p.T27P | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66171172; called by muse, mutect2, varscan2
- FSIP2 | c.19312G>A p.E6438K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); catalogued as COSV58086972, COSV58104330; called by muse, mutect2, varscan2
- GALC | c.1867G>T p.E623* | Nonsense Mutation (SNP) | VAF 39/253 reads (15%) | catalogued as COSV54328342; called by muse, mutect2, varscan2
- GALNT18 | c.1591C>A p.L531M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57153985; called by muse, mutect2, varscan2
- GDAP1L1 | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.457); catalogued as COSV61157151; called by muse, mutect2, varscan2
- GFOD2 | c.365A>T p.N122I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV52059214; called by muse, mutect2, varscan2
- GHRHR | c.713C>G p.S238* | Nonsense Mutation (SNP) | VAF 14/196 reads (7%) | catalogued as COSV58197541; called by muse, mutect2
- GJA5 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99605819; called by muse, mutect2, varscan2
- GLDC | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58683106; called by muse, mutect2, varscan2
- GLRA4 | c.728C>A p.T243N | Missense Mutation (SNP) | VAF 53/67 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV65456536; called by muse, mutect2, varscan2
- GPC2 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV52785965; called by muse, mutect2, varscan2
- GPC6 | c.637C>A p.R213S | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65494787, COSV65525111; called by muse, mutect2, varscan2
- GRM1 | c.2351C>T p.A784V | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51222116; called by muse, mutect2, varscan2
- H1-4 | c.74G>C p.R25P | Missense Mutation (SNP) | VAF 64/87 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV56802747, COSV56802752; called by muse, mutect2, varscan2
- HCK | c.1274C>A p.A425D | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52945546; called by muse, mutect2, varscan2
- HCN1 | c.2159C>A p.A720D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV57527223, COSV57544260; called by muse, varscan2
- HEATR1 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63982361; called by muse, mutect2, varscan2
- HENMT1 | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV64230536; called by muse, mutect2, varscan2
- HIVEP3 | c.4190G>C p.R1397T | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV56020180; called by muse, mutect2, varscan2
- HOOK3 | c.1692G>T p.K564N | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV56885765; called by muse, mutect2, varscan2
- HOXA5 | c.458C>A p.A153D | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as COSV56074299; called by muse, mutect2, varscan2
- HSPH1 | c.831G>A p.M277I | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60712766; called by muse, mutect2, varscan2
- HTR2B | c.1085T>A p.L362Q | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV99295452; called by muse, mutect2, varscan2
- HUWE1 | c.12466G>T p.G4156C | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53338856; called by muse, mutect2, varscan2
- IGFL1 | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 80/114 reads (70%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV71443649; called by muse, mutect2, varscan2
- IL17RE | c.1367G>T p.G456V | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55969659; called by muse, mutect2, varscan2
- INSRR | c.3356G>T p.R1119L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755716153, COSV100948102, COSV63873427; called by muse, mutect2, varscan2
- ISLR2 | c.1221C>G p.S407R | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV62302960; called by muse, mutect2, varscan2
- ITGA2 | c.1810A>C p.I604L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV56864211; called by muse, mutect2, varscan2
- ITPR2 | c.5939A>G p.K1980R | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV67273602; called by muse, mutect2, varscan2
- ITPR2 | c.2337T>A p.C779* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV67273606; called by muse, mutect2, varscan2
- IVD | c.898G>A p.A300T (on ENST00000651168; = p.A297T on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV51100233; called by muse, mutect2, varscan2
- KANSL1L | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV55995030; called by muse, mutect2, varscan2
- KCNC4 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs370020605, COSV63926229; called by muse, mutect2, varscan2
- KCNH7 | c.262G>C p.G88R | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59806743; called by muse, mutect2, varscan2
- KDM5A | c.2628G>A p.M876I | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV66994959; called by muse, mutect2, varscan2
- KEAP1 | c.1525G>T p.G509W | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50565587; called by muse, mutect2, varscan2
- KIAA1109 | c.11836C>T p.P3946S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs1435679137, COSV52685299; called by muse, mutect2, varscan2
- KIAA2026 | c.1460G>C p.R487T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as COSV67356479, COSV67356712; called by muse, mutect2, varscan2
- KIF15 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); catalogued as COSV58163481; called by muse, mutect2, varscan2
- KIF26B | c.2609C>A p.P870H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100833451; called by muse, mutect2, varscan2
- KLK10 | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV59399041; called by muse, mutect2, varscan2
- KLK13 | c.617C>G p.T206R | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV50067299, COSV99335455; called by muse, mutect2, varscan2
- KRTAP10-4 | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.263); catalogued as COSV59972625; called by muse, mutect2, varscan2
- KRTAP5-1 | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.367); catalogued as COSV66298960; called by muse, varscan2
- KTN1 | c.2400_2402del p.K801del | In Frame Del (DEL) | VAF 6/72 reads (8%) | catalogued as rs779707035; called by mutect2, pindel
- KYNU | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1246433975, COSV99934026; called by muse, mutect2, varscan2
- LAMA1 | c.6688A>G p.T2230A | Missense Mutation (SNP) | VAF 47/72 reads (65%) | SIFT tolerated (0.27); PolyPhen benign (0.433); catalogued as COSV67541238; called by muse, mutect2, varscan2
- LAMA2 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70343635, COSV70352482; called by muse, mutect2, varscan2
- LAMA4 | c.1165C>T p.H389Y (on ENST00000230538 / NM_001105206.3; = p.H382Y on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.212); catalogued as COSV57902130; called by muse, mutect2, varscan2
- LGI2 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); catalogued as COSV66123623; called by muse, mutect2, varscan2
- LMBRD1 | c.1622C>A p.S541* (on ENST00000649011; = p.S519* on NM_018368.4) | Nonsense Mutation (SNP) | VAF 5/52 reads (10%) | catalogued as COSV65298590; called by mutect2, varscan2
- LMOD1 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66173417; called by muse, mutect2, varscan2
- LRP1 | c.3569G>A p.G1190D | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs760065131, COSV54519967; called by muse, mutect2, varscan2
- LRRC10 | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100825525; called by muse, mutect2, varscan2
- LRRC32 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.649); catalogued as COSV52634524; called by muse, mutect2, varscan2
- LRRC4C | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53417523, COSV99539805; called by muse, mutect2, varscan2
- LYZL1 | c.510C>A p.N170K (on ENST00000375500; = p.N124K on NM_032517.6) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.69); PolyPhen benign (0.112); catalogued as COSV64966740; called by muse, mutect2, varscan2
- MAGEC3 | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV71610095; called by muse, mutect2, varscan2
- MARCHF3 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100428152; called by muse, mutect2, varscan2
- MARCO | c.810G>C p.M270I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV59054549, COSV59056687; called by muse, mutect2, varscan2
- MASP1 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs780560675, COSV51462360; called by muse, mutect2, varscan2
- MBD1 | c.572G>T p.C191F | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54004736; called by muse, mutect2, varscan2
- MEGF6 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs374274993; called by muse, mutect2, varscan2
- MEOX2 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.104); catalogued as COSV56292919; called by muse, mutect2, varscan2
- MIA2 | c.1258G>T p.D420Y | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV54485296; called by muse, mutect2, varscan2
- MIA3 | c.495G>T p.M165I | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV60515853; called by muse, mutect2, varscan2
- MIA3 | c.4990A>T p.N1664Y | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV60515864; called by muse, mutect2, varscan2
- MKNK1 | c.1168G>C p.A390P | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57861412, COSV57862329; called by muse, mutect2, varscan2
- MMEL1 | c.1075C>A p.L359I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV56521421, COSV56524299; called by muse, mutect2, varscan2
- MMEL1 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); catalogued as rs148947796; called by muse, mutect2, varscan2
- MPP6 | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); catalogued as COSV56041069; called by muse, mutect2, varscan2
- MUC5AC | c.15702C>A p.Y5234* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as COSV100611599; called by muse, mutect2, varscan2
- MUC7 | c.565A>T p.T189S | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as COSV59219562; called by muse, varscan2
- MYH1 | c.2093G>T p.R698M | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs1456972136, COSV56853690; called by muse, mutect2, varscan2
- MYH7 | c.4895C>T p.A1632V | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs1435525455, COSV62521855; called by muse, mutect2, varscan2
- MYH7B | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as rs200544338; called by muse, mutect2
- MYLIP | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV62767308; called by muse, mutect2, varscan2
- MYO18A | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs749103234, COSV62870902, COSV62875150; called by muse, mutect2, varscan2
- MYOF | c.3142C>T p.Q1048* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100826131; called by muse, mutect2, varscan2
- N4BP3 | c.293G>T p.S98I | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99200829; called by muse, mutect2, varscan2
- NAALADL1 | c.1207C>A p.R403S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60525180; called by muse, mutect2, varscan2
- NADK2 | c.975G>T p.R325S (on ENST00000381937 / NM_001085411.3; = p.R162S on NM_153013.4) | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV56938513; called by muse, mutect2, varscan2
- NALCN | c.3908G>A p.G1303D | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51919522; called by muse, mutect2, varscan2
- NAV3 | c.5621C>A p.S1874Y (on ENST00000397909 / NM_001024383.2; = p.S1852Y on NM_014903.6) | Missense Mutation (SNP) | VAF 57/76 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV57100094; called by muse, mutect2, varscan2
- NDST4 | c.373A>G p.K125E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV99997911; called by muse, mutect2, varscan2
- NEK1 | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV71457482; called by muse, mutect2, varscan2
- NFKB1 | c.865G>T p.E289* (on ENST00000394820 / NM_001382627.1; = p.E290* on NM_003998.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV56959497; called by muse, mutect2, varscan2
- NFRKB | c.1316G>C p.R439P (on ENST00000446488 / NM_001143835.2; = p.R464P on NM_006165.3) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.694); catalogued as COSV58759572; called by muse, mutect2, varscan2
- NLRP14 | c.2893G>T p.G965W | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55070152; called by muse, mutect2, varscan2
- NLRP3 | c.1184G>T p.S395I | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV60229025; called by muse, mutect2, varscan2
- NOP56 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61390934; called by muse, mutect2, varscan2
- NPHP3 | c.1405G>T p.D469Y | Missense Mutation (SNP) | VAF 140/226 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV58632159; called by muse, mutect2, varscan2
- NRXN1 | c.3766G>T p.G1256W | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100640814, COSV60499596, COSV60512257, COSV60523646; called by muse, mutect2, varscan2
- NRXN1 | c.3509G>T p.S1170I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58476435; called by muse, mutect2, varscan2
- NRXN2 | c.3344G>A p.W1115* | Nonsense Mutation (SNP) | VAF 57/135 reads (42%) | catalogued as COSV55459838; called by muse, mutect2, varscan2
- NTNG1 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV53963546, COSV99639538; called by muse, mutect2, varscan2
- NTNG2 | c.1209G>T p.E403D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as COSV62368036; called by muse, mutect2, varscan2
- NUP210L | c.3272A>G p.K1091R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1485950180, COSV55153669; called by muse, mutect2
- NUP93 | c.589G>T p.V197L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV57432582; called by muse, mutect2, varscan2
- OLAH | c.256C>G p.L86V (on ENST00000378228 / NM_001039702.3; = p.L139V on NM_018324.3) | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs771658653, COSV65493610; called by muse, mutect2, varscan2
- OR10J1 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.17); catalogued as COSV71129279; called by muse, mutect2, varscan2
- OR12D3 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT tolerated (0.46); PolyPhen benign (0.033); catalogued as rs761869986, COSV101011477; called by muse, mutect2, varscan2
- OR1C1 | c.655G>T p.G219* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV68715336, COSV68716066; called by muse, mutect2, varscan2
- OR2D3 | c.982C>A p.H328N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV53494154, COSV53494252; called by muse, mutect2, varscan2
- OR2F1 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 70/268 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67331764; called by muse, mutect2, varscan2
- OR2F2 | c.671C>A p.T224N | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV101283857; called by muse, mutect2, varscan2
- OR2T3 | c.38C>A p.A13E | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV62083081; called by muse, mutect2, varscan2
- OR4K17 | c.59C>A p.S20Y | Missense Mutation (SNP) | VAF 141/354 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs372021676, COSV59648225; called by muse, mutect2, varscan2
- OR4M1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 91/789 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV60062715; called by muse, mutect2, varscan2
- OR51A4 | c.454T>A p.F152I | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV66749844; called by muse, mutect2, varscan2
- OR51G2 | c.428A>T p.N143I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.333); catalogued as rs1452282867, COSV58994142; called by muse, mutect2, varscan2
- OR52E4 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1350276264, COSV100389264, COSV57625603; called by muse, mutect2, varscan2
- OR5D16 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65721457; called by muse, mutect2, varscan2
- OR5T3 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV57381911; called by muse, mutect2, varscan2
- OR8K5 | c.59G>C p.R20P | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.107); catalogued as COSV100537295, COSV57888322, COSV57890208; called by muse, mutect2, varscan2
- OR8U1 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1300922441, COSV100164135; called by muse, mutect2, varscan2
- OR9A2 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs374520156; called by muse, mutect2, varscan2
- OTUD7A | c.896T>A p.V299E (on ENST00000307050 / NM_001382637.1; = p.V292E on NM_130901.3) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV61041525; called by muse, mutect2, varscan2
- PABPC5 | c.1068A>T p.K356N | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV57042240; called by muse, mutect2, varscan2
- PCDH8 | c.2912G>T p.G971V | Missense Mutation (SNP) | VAF 139/173 reads (80%) | SIFT tolerated (0.11); PolyPhen benign (0.368); catalogued as COSV100131104, COSV58814288; called by muse, mutect2, varscan2
- PCDHGA5 | c.2349G>C p.E783D | Missense Mutation (SNP) | VAF 75/118 reads (64%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.019); catalogued as rs1414514905, COSV53997772; called by muse, mutect2, varscan2
- PCDHGB2 | c.304T>A p.C102S | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53997756; called by muse, mutect2, varscan2
- PCNX4 | c.2759G>A p.C920Y (on ENST00000406854 / NM_001330177.2; = p.C686Y on NM_022495.5) | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV58306350; called by muse, mutect2, varscan2
- PEX2 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100824941; called by muse, mutect2, varscan2
- PGM3 | c.1258A>G p.I420V | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs781101543, COSV52285274; called by muse, mutect2, varscan2
- PKHD1 | c.3669G>C p.R1223S | Missense Mutation (SNP) | VAF 60/73 reads (82%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV61885586, COSV61888287; called by muse, mutect2, varscan2
- PLCL2 | c.1300C>G p.H434D (on ENST00000615277 / NM_001144382.2; = p.H308D on NM_015184.5) | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67623894, COSV67623985; called by muse, mutect2, varscan2
- PLXDC1 | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV59552837; called by muse, mutect2, varscan2
- POLR3A | c.1413G>C p.L471F | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64931637; called by muse, mutect2, varscan2
- PPDPFL | c.119A>G p.D40G | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.199); catalogued as COSV57461942; called by muse, mutect2, varscan2
- PPP1R36 | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV53903331, COSV53903709; called by muse, mutect2, varscan2
- PRDM16 | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV54601724; called by muse, mutect2
- PRDM4 | c.893C>G p.S298C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.319); catalogued as COSV57306907; called by muse, mutect2, varscan2
- PRKCB | c.1741G>T p.G581C | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV57792150; called by muse, mutect2, varscan2
- PRKCZ | c.562A>G p.M188V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs775475925, COSV66069785; called by muse, mutect2, varscan2
- PRMT5 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV53547613; called by muse, mutect2, varscan2
- PROSER2 | c.57del p.S20Afs*32 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as COSV53205674; called by mutect2, pindel, varscan2
- PRR27 | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.171); catalogued as COSV60641158; called by muse, mutect2
- PRSS1 | c.370T>A p.S124T | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV61195583; called by muse, varscan2
- PRUNE2 | c.1281C>G p.D427E | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65044810; called by muse, mutect2, varscan2
- PTCD1 | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52866246, COSV99464120; called by muse, mutect2, varscan2
- PTGDR | c.471C>A p.S157R | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.482); catalogued as rs1202922726, COSV60094307, COSV60094646; called by muse, mutect2, varscan2
- PTPRB | c.5044C>G p.P1682A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV54248412; called by muse, mutect2, varscan2
- PTPRZ1 | c.5222C>G p.T1741R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66442255; called by muse, mutect2, varscan2
- PYGL | c.1882G>T p.A628S | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV53587546; called by muse, mutect2, varscan2
- QSER1 | c.3526A>T p.T1176S (on ENST00000399302; = p.T1305S on NM_001076786.3) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV67901298; called by muse, mutect2, varscan2
- RAB37 | c.524A>G p.K175R (on ENST00000392613 / NM_001006638.3; = p.K168R on NM_175738.5) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as COSV52854266; called by muse, mutect2, varscan2
- RAD54L2 | c.2546G>A p.R849Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs918492089, COSV56580438; called by muse, mutect2, varscan2
- RANBP10 | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.158); catalogued as COSV58160009; called by muse, mutect2, varscan2
- RASSF2 | c.492C>G p.I164M | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV65082794; called by muse, mutect2, varscan2
- REG3G | c.11C>A p.P4H | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs1297208335, COSV55450834; called by muse, mutect2, varscan2
- RET | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.039); catalogued as COSV100394635, COSV104412398; called by muse, mutect2
- RGS13 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 23/112 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV67346424, COSV67346460; called by muse, mutect2, varscan2
- RGS3 | c.364C>G p.Q122E | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV58283411; called by muse, mutect2, varscan2
- RGS7 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 91/186 reads (49%) | catalogued as COSV58535665; called by muse, mutect2, varscan2
- RIMS2 | c.3818T>C p.I1273T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51705416; called by muse, varscan2
- RNF207 | c.127G>C p.D43H | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.805); catalogued as COSV65008039; called by muse, mutect2, varscan2
- RP1L1 | c.6315G>T p.E2105D | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.662); catalogued as rs1482827329, COSV66758255; called by muse, mutect2, varscan2
- RREB1 | c.1807G>T p.E603* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV58562136; called by muse, mutect2, varscan2
- RUNDC1 | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs756700931, COSV100865896; called by muse, mutect2, varscan2
- RUNX1T1 | c.949C>T p.H317Y (on ENST00000265814 / NM_001198628.1; = p.H290Y on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.424); catalogued as COSV56156667; called by muse, mutect2, varscan2
- RYR1 | c.8159C>G p.S2720* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as COSV62104818, COSV62108390; called by muse, mutect2, varscan2
- RYR2 | c.13002G>T p.M4334I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.977); catalogued as COSV63687284, COSV63702121; called by muse, mutect2, varscan2
- SAV1 | c.627G>C p.W209C | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV61205661; called by muse, mutect2, varscan2
- SCN1A | c.4930G>T p.G1644C (on ENST00000303395 / NM_001202435.3; = p.G1633C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559105762, COSV57680320, COSV57687628; called by muse, mutect2, varscan2
- SCN2A | c.4991G>A p.G1664D | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51850035; called by muse, mutect2, varscan2
- SCN3A | c.4106C>A p.T1369K | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.817); catalogued as COSV51818438; called by muse, mutect2, varscan2
- SCN3A | c.2992G>C p.D998H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51818461; called by muse, mutect2, varscan2
- SDK1 | c.4111G>C p.E1371Q | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.834); catalogued as rs1425526722, COSV67373691; called by muse, mutect2, varscan2
- SEC31B | c.2098G>T p.A700S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100947473; called by muse, mutect2, varscan2
- SEC31B | c.2097G>T p.W699C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV100947474; called by muse, mutect2, varscan2
- SEMA4G | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.638); catalogued as COSV52970579; called by muse, mutect2
- SERPINA3 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555386065, COSV67586764; called by muse, mutect2, varscan2
- SGIP1 | c.1088C>A p.P363H | Missense Mutation (SNP) | VAF 71/121 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV52775187; called by muse, mutect2, varscan2
- SGIP1 | c.1674C>A p.D558E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99392968; called by muse, mutect2, varscan2
- SGK2 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.292); catalogued as COSV58314534; called by muse, mutect2, varscan2
- SH3D19 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 12/278 reads (4%) | catalogued as COSV58792383; called by muse, mutect2
- SIX6 | c.285C>A p.H95Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59803029; called by muse, mutect2, varscan2
- SLC10A7 | c.993G>T p.K331N | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV53888023; called by muse, mutect2, varscan2
- SLC12A4 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.226); catalogued as rs373495514; called by muse, mutect2, varscan2
- SLC14A2 | c.1041C>A p.S347R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV54905936, COSV54912466; called by muse, mutect2, varscan2
- SLC17A9 | c.725+1G>A p.X242_splice | Splice Site (SNP) | VAF 12/38 reads (32%) | catalogued as COSV64847911; called by muse, mutect2, varscan2
- SLC22A6 | c.1091G>C p.G364A | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64560704; called by muse, mutect2, varscan2
- SLC24A5 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.996); catalogued as COSV58318461, COSV58319800; called by muse, mutect2, varscan2
- SLC26A5 | c.898G>T p.G300* | Nonsense Mutation (SNP) | VAF 24/92 reads (26%) | catalogued as COSV59701896, COSV59703331; called by muse, mutect2, varscan2
- SLC27A6 | c.1172C>A p.S391Y | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs572563525, COSV52485730; called by muse, mutect2, varscan2
- SLC2A10 | c.304G>T p.V102F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV63715602; called by muse, mutect2, varscan2
- SLC35F1 | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64506493; called by muse, mutect2, varscan2
- SLC45A2 | c.415G>C p.V139L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV56874007; called by muse, mutect2
- SLC4A9 | c.898C>T p.R300C (on ENST00000507527 / NM_001258428.2; = p.R276C on NM_031467.3) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs1245745759, COSV50183759, COSV50184127; called by muse, mutect2, varscan2
- SLCO2B1 | c.1752G>T p.M584I | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV56937707; called by muse, varscan2
- SLIT1 | c.4058A>T p.Q1353L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.272); catalogued as COSV56595058, COSV56596033; called by muse, mutect2, varscan2
- SLITRK6 | c.1177C>G p.H393D | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV68391082; called by muse, mutect2, varscan2
- SP140L | c.559A>T p.S187C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as COSV54746418; called by muse, mutect2
- SPANXN3 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV65140370, COSV65140655; called by muse, mutect2, varscan2
- SPARCL1 | c.74C>G p.S25C | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV56805418; called by muse, mutect2, varscan2
- SSH3 | c.1319T>A p.L440Q | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV57386023; called by muse, mutect2, varscan2
- STAM2 | c.1363A>G p.T455A | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV55732985; called by muse, mutect2, varscan2
- SYTL5 | c.1063-1G>T p.X355_splice | Splice Site (SNP) | VAF 20/30 reads (67%) | catalogued as COSV52903603; called by muse, mutect2, varscan2
- TAAR2 | c.962G>T p.W321L (on ENST00000367931 / NM_001033080.1; = p.W276L on NM_014626.3) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51579638; called by muse, mutect2, varscan2
- TAS2R1 | c.373C>A p.L125M | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as rs780161104, COSV101225871, COSV66778123; called by muse, mutect2, varscan2
- TBX5 | c.465C>A p.F155L | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV59863620; called by muse, mutect2, varscan2
- TBXAS1 | c.1333T>A p.W445R | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54950663; called by muse, mutect2, varscan2
- TDP1 | c.1180G>T p.V394F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV59644779; called by muse, mutect2, varscan2
- TENM1 | c.5479G>A p.G1827R | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64438541; called by muse, mutect2, varscan2
- TESK2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as rs1272647065, COSV59155636; called by muse, mutect2, varscan2
- THNSL1 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64479694; called by muse, varscan2
- TJP1 | c.4067G>A p.R1356Q | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.961); catalogued as rs762084848, COSV62040578; called by muse, mutect2, varscan2
- TLL1 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.811); catalogued as COSV50307970; called by muse, mutect2, varscan2
- TLN2 | c.5557G>T p.D1853Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60893002; called by muse, mutect2, varscan2
- TMIGD1 | c.625C>A p.H209N | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV61029016; called by muse, mutect2, varscan2
- TMPPE | c.557A>T p.Q186L | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100257709; called by muse, mutect2, varscan2
- TNNT3 | c.275C>A p.A92D (on ENST00000397301 / NM_001367846.1; = p.A81D on NM_006757.4) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.216); catalogued as rs1483036041, COSV99548768; called by muse, mutect2, varscan2
- TNS1 | c.1678C>A p.P560T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs372897397, COSV50736672; called by muse, mutect2, varscan2
- TP53 | c.456del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 30/50 reads (60%) | catalogued as COSV52765928, COSV52978254, COSV53086786; called by mutect2, varscan2
- TRO | c.3368C>G p.P1123R | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as COSV51505196; called by muse, mutect2, varscan2
- TRPV6 | c.2216G>C p.R739P | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100844061, COSV63892873; called by muse, mutect2, varscan2
- TSHZ3 | c.2166G>C p.L722F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53677921; called by muse, mutect2, varscan2
- TTC21B | c.1376G>C p.C459S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV54632536, COSV54633082; called by muse, mutect2, varscan2
- TTN | c.16043C>A p.P5348H (on ENST00000591111; = p.P4421H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/111 reads (17%) | PolyPhen probably damaging (0.999); catalogued as COSV60225270, COSV60360530; called by muse, mutect2, varscan2
- TUBB8 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV59117070; called by muse, mutect2, varscan2
- TUBG2 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 13/126 reads (10%) | catalogued as COSV52218969; called by muse, mutect2, varscan2
- UGT2B7 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV59444808; called by muse, mutect2, varscan2
- UNC5D | c.1858A>T p.I620F | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV54818518; called by muse, mutect2, varscan2
- UNC79 | c.760G>T p.V254F (on ENST00000393151 / NM_001346218.2; = p.V77F on NM_020818.5) | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56401158; called by muse, mutect2, varscan2
- USH2A | c.7100G>T p.G2367V | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100242809; called by muse, mutect2, varscan2
- UTRN | c.9305G>A p.R3102Q | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776348759, COSV62304919; called by muse, mutect2, varscan2
- VCAN | c.8899G>T p.E2967* | Nonsense Mutation (SNP) | VAF 56/87 reads (64%) | catalogued as COSV54112155; called by muse, mutect2, varscan2
- VIL1 | c.367G>C p.A123P | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV50285400; called by muse, mutect2, varscan2
- VPS13A | c.5186T>G p.I1729S | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV62434932; called by muse, mutect2, varscan2
- VTA1 | c.336-1G>T p.X112_splice | Splice Site (SNP) | VAF 30/164 reads (18%) | catalogued as COSV100859266; called by muse, mutect2, varscan2
- VTA1 | c.336A>T p.K112N | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV100859267; called by muse, mutect2, varscan2
- VWA3B | c.3141T>A p.N1047K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV68245137; called by muse, mutect2, varscan2
- WDR25 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as COSV58935012; called by muse, mutect2, varscan2
- WIPI1 | c.972G>C p.Q324H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV50930899; called by muse, mutect2, varscan2
- XIRP2 | c.4873G>A p.E1625K (on ENST00000628543; = p.E1800K on NM_152381.6) | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.339); catalogued as COSV54720768, COSV54723650; called by muse, mutect2, varscan2
- XRN2 | c.1828C>A p.L610I | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.376); catalogued as COSV65870862; called by muse, mutect2, varscan2
- YY1AP1 | c.632A>G p.Q211R (on ENST00000295566 / NM_139118.2; = p.Q134R on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99804727; called by muse, mutect2, varscan2
- ZC3H12B | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 92/112 reads (82%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as COSV59050346; called by muse, mutect2, varscan2
- ZFHX4 | c.2368A>T p.K790* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV51479850; called by muse, mutect2, varscan2
- ZFP57 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 78/111 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV65305828, COSV65306651; called by muse, mutect2, varscan2
- ZNF334 | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs371979289, COSV61619577; called by muse, mutect2, varscan2
- ZNF521 | c.1108A>T p.M370L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.114); catalogued as COSV64129921; called by muse, mutect2, varscan2
- ZNF595 | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs1305588397, COSV59552234; called by muse, mutect2, varscan2
- ZNF676 | c.1822G>T p.V608F (on ENST00000650058; = p.V576F on NM_001001411.3) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV68094084, COSV68094186; called by muse, mutect2, varscan2
- ARID1A | c.2890delinsCT p.S964Lfs*43 | Frame Shift Ins (INS) | VAF 10/44 reads (23%) | called by pindel, varscan2*
- ENPP3 | c.2380_2381del p.P794Gfs*26 | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | called by mutect2, pindel, varscan2
- FN1 | c.605dup p.K203Efs*26 | Frame Shift Ins (INS) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- ITGA1 | c.648_659delinsT p.E216Dfs*2 | Frame Shift Del (DEL) | VAF 25/46 reads (54%) | called by pindel, varscan2*
- MRC1 | c.4213C>T p.L1405F | Missense Mutation (SNP) | VAF 77/368 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR3A3 | c.266C>A p.A89E | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.15); called by muse, varscan2
- PAX3 | c.1121del p.S374Wfs*7 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- PTPRO | c.2686del p.L896Ffs*14 | Frame Shift Del (DEL) | VAF 45/95 reads (47%) | called by mutect2, pindel, varscan2
- AADACL4 | c.825A>G p.P275= | Silent (SNP) | VAF 41/123 reads (33%) | catalogued as COSV66106853; called by muse, mutect2, varscan2
- ABCC11 | c.1092C>T p.I364= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV62324846; called by muse, mutect2, varscan2
- ADAMTS12 | c.2725C>T p.L909= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as COSV61271981; called by muse, mutect2, varscan2
- ADD1 | c.1113G>A p.Q371= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV53272235; called by muse, mutect2, varscan2
- ADGRG4 | c.6919C>A p.R2307= | Silent (SNP) | VAF 27/37 reads (73%) | catalogued as rs376547734, COSV54959019; called by muse, mutect2, varscan2
- AHNAK | c.8847C>A p.P2949= | Silent (SNP) | VAF 50/234 reads (21%) | catalogued as COSV57223612; called by muse, mutect2, varscan2
- AKAP6 | c.1960C>T p.L654= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV55224881; called by muse, mutect2, varscan2
- ARHGAP5 | c.3597A>T p.P1199= | Silent (SNP) | VAF 55/142 reads (39%) | catalogued as COSV61538188; called by muse, mutect2, varscan2
- BSCL2 | c.654G>C p.A218= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV54017103; called by muse, mutect2, varscan2
- CA3 | c.237G>A p.L79= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV53410633; called by muse, mutect2, varscan2
- CACNA1A | c.4740C>T p.A1580= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV64206196; called by muse, mutect2, varscan2
- CASZ1 | c.1923C>T p.A641= | Silent (SNP) | VAF 45/70 reads (64%) | catalogued as COSV59739167; called by muse, mutect2, varscan2
- CAVIN2 | c.1173G>A p.Q391= | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as COSV58425088; called by muse, mutect2, varscan2
- CCDC91 | c.912A>T p.V304= | Silent (SNP) | VAF 61/154 reads (40%) | catalogued as COSV60346069; called by muse, mutect2, varscan2
- CCM2L | c.48C>A p.I16= | Silent (SNP) | VAF 52/198 reads (26%) | catalogued as COSV52951743; called by muse, mutect2, varscan2
- CD38 | c.102C>A p.I34= | Silent (SNP) | VAF 42/153 reads (27%) | catalogued as COSV56891974; called by muse, mutect2, varscan2
- CDH6 | c.786C>T p.N262= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as rs753390985, COSV54064859; called by muse, mutect2, varscan2
- CDH7 | c.2316C>A p.L772= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV59884415, COSV59889194, COSV59890578; called by muse, mutect2, varscan2
- CFHR1 | c.138T>C p.P46= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV57628304; called by muse, mutect2, varscan2
- CLDN12 | c.192C>T p.S64= | Silent (SNP) | VAF 57/117 reads (49%) | catalogued as rs970838406, COSV55307597; called by muse, mutect2, varscan2
- CPA4 | c.1137C>T p.F379= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV55984426; called by muse, mutect2, varscan2
- CPNE5 | c.1701C>A p.P567= | Silent (SNP) | VAF 54/80 reads (68%) | catalogued as COSV55198549; called by muse, mutect2, varscan2
- CRAMP1 | c.2301G>C p.T767= | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as rs539483291, COSV51960673, COSV51961439, COSV51964698; called by muse, mutect2, varscan2
- CRYBA2 | c.171C>T p.A57= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as rs771180861, COSV99838148; called by muse, mutect2, varscan2
- CXADR | c.172C>T p.L58= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs1481190612, COSV53030271; called by muse, mutect2, varscan2
- CYP3A5 | c.786C>T p.N262= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs764808178, COSV56121801; called by muse, mutect2, varscan2
- DDX23 | c.735G>A p.K245= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as COSV57285350; called by muse, mutect2, varscan2
- DENND2A | c.2121C>T p.F707= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV52048013; called by muse, mutect2, varscan2
- DNAH5 | c.10068G>A p.L3356= | Silent (SNP) | VAF 78/197 reads (40%) | catalogued as rs769718739, COSV54241657; called by muse, mutect2, varscan2
- DNAH7 | c.5658A>T p.R1886= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV56776683; called by muse, mutect2, varscan2
- DNER | c.480G>A p.Q160= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV59172029; called by muse, mutect2, varscan2
- DSC1 | c.2412G>A p.K804= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as rs747125495, COSV57149109; called by muse, mutect2, varscan2
- DSG1 | c.2367A>T p.T789= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as COSV57137896; called by muse, mutect2, varscan2
- DTWD2 | c.717C>T p.Y239= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs776905929, COSV58368110; called by muse, mutect2, varscan2
- DYNLL2 | c.24C>T p.I8= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV101651069; called by muse, mutect2, varscan2
- DYSF | c.3741G>T p.P1247= | Silent (SNP) | VAF 72/162 reads (44%) | catalogued as COSV50505611; called by muse, mutect2, varscan2
- E2F7 | c.1566G>A p.V522= | Silent (SNP) | VAF 56/79 reads (71%) | catalogued as COSV59742209; called by muse, mutect2, varscan2
- ELOVL2 | c.192C>T p.L64= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV61156424; called by muse, mutect2, varscan2
- ERMN | c.444G>A p.K148= | Silent (SNP) | VAF 53/122 reads (43%) | catalogued as COSV68075556; called by muse, mutect2, varscan2
- EXO1 | c.1155A>T p.S385= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as COSV62218847; called by muse, mutect2, varscan2
- FAP | c.1440C>A p.R480= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV51865253; called by muse, mutect2, varscan2
- FBLIM1 | c.171G>A p.A57= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs767469745, COSV60029773, COSV60030920; called by muse, mutect2, varscan2
- FBXL7 | c.1257C>G p.G419= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV61650039; called by muse, mutect2, varscan2
- FLNB | c.6285C>G p.V2095= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as COSV55888671; called by muse, mutect2, varscan2
- FSTL5 | c.225C>T p.H75= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV60207532; called by muse, mutect2, varscan2
- GLI3 | c.2499C>G p.L833= | Silent (SNP) | VAF 40/177 reads (23%) | catalogued as COSV67892536; called by muse, mutect2, varscan2
- GRIN3B | c.1461G>A p.L487= | Silent (SNP) | VAF 23/32 reads (72%) | catalogued as rs1467812852, COSV99312933; called by muse, mutect2, varscan2
- GSX1 | c.774G>T p.R258= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as rs189831013, COSV100262632; called by muse, mutect2, varscan2
- HCN1 | c.2229G>A p.P743= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV57510678; called by muse, varscan2
- HECW1 | c.273G>A p.G91= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV67826654; called by muse, mutect2
- IFNGR1 | c.1221C>T p.H407= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs765407922, COSV62992475; called by muse, mutect2, varscan2
- INSC | c.609T>A p.V203= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV65412207; called by muse, mutect2, varscan2
- KDM4B | c.33C>T p.P11= | Silent (SNP) | VAF 112/161 reads (70%) | catalogued as rs368489068; called by muse, mutect2, varscan2
- KDM6A | c.2007C>T p.L669= | Silent (SNP) | VAF 21/26 reads (81%) | catalogued as COSV65043502; called by muse, mutect2, varscan2
- KIAA1549L | c.735C>A p.L245= (on ENST00000321505; = p.L542= on NM_012194.3) | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as COSV55778263; called by muse, mutect2, varscan2
- KIF26B | c.2610C>A p.P870= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs1453988772, COSV100833455; called by muse, mutect2, varscan2
- KIF2B | c.312G>T p.S104= | Silent (SNP) | VAF 67/149 reads (45%) | catalogued as rs543663752, COSV52129067, COSV52133640; called by muse, mutect2, varscan2
- KIR2DL1 | c.945C>T p.I315= | Silent (SNP) | VAF 62/183 reads (34%) | called by muse, mutect2, varscan2
- LEFTY1 | c.258C>A p.A86= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV55283696; called by muse, mutect2, varscan2
- LMNB2 | c.1293G>T p.L431= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV57589825; called by muse, mutect2, varscan2
- LRP1B | c.12012G>A p.L4004= | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as COSV67233790; called by muse, mutect2, varscan2
- LRRC73 | c.183C>A p.L61= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99447539; called by muse, mutect2
- LRRK1 | c.4419C>A p.A1473= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV52621792; called by muse, mutect2, varscan2
- MICAL2 | c.1722G>T p.V574= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV56323598; called by muse, mutect2, varscan2
- MYH1 | c.5439G>A p.K1813= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV56853678; called by muse, mutect2, varscan2
- NFIB | c.894T>A p.A298= | Silent (SNP) | VAF 43/65 reads (66%) | catalogued as COSV101101456; called by muse, mutect2, varscan2
- NLRP14 | c.60G>A p.E20= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV55070142; called by muse, mutect2, varscan2
- NT5C3A | c.868C>T p.L290= (on ENST00000610140 / NM_001374335.1; = p.L256= on NM_016489.13) | Silent (SNP) | VAF 37/136 reads (27%) | catalogued as COSV54238250; called by muse, mutect2, varscan2
- NTNG1 | c.204G>T p.P68= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as COSV99639528; called by muse, mutect2, varscan2
- OR10Q1 | c.75T>C p.T25= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as COSV57471400; called by muse, mutect2, varscan2
- OR13C9 | c.618C>T p.F206= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs1253761136, COSV52243068; called by muse, mutect2, varscan2
- OR1N1 | c.762C>T p.F254= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV59195759; called by muse, mutect2, varscan2
- OR2F2 | c.672C>A p.T224= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as COSV101283858, COSV68832793; called by muse, mutect2, varscan2
- OR4X1 | c.636G>A p.L212= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs779128456, COSV60723465; called by muse, mutect2, varscan2
- OR8J1 | c.810T>A p.T270= | Silent (SNP) | VAF 33/165 reads (20%) | catalogued as COSV57319385; called by muse, mutect2, varscan2
- OR9K2 | c.351C>A p.I117= (on ENST00000305377; = p.I95= on NM_001005243.1) | Silent (SNP) | VAF 69/109 reads (63%) | catalogued as rs1466164160, COSV59532210, COSV59532781; called by muse, mutect2, varscan2
- PARL | c.1116C>T p.P372= | Silent (SNP) | VAF 75/227 reads (33%) | catalogued as COSV57701605; called by muse, mutect2, varscan2
- PASK | c.2604C>T p.N868= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as rs554640041, COSV52157085; called by muse, mutect2, varscan2
- PAX4 | c.63C>A p.P21= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV58390189; called by muse, mutect2, varscan2
- PCDH10 | c.750C>T p.F250= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV52100002; called by muse, mutect2, varscan2
- PCDH9 | c.255T>A p.I85= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV60574056; called by muse, mutect2, varscan2
- PCDHB10 | c.1548C>G p.L516= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV53381826; called by muse, mutect2, varscan2
- PLB1 | c.4068C>T p.A1356= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs758044405, COSV59832005; called by muse, mutect2, varscan2
- PTBP2 | c.342A>G p.A114= (on ENST00000426398 / NM_001300986.2; = p.A106= on NM_021190.4) | Silent (SNP) | VAF 62/101 reads (61%) | catalogued as COSV64625804; called by muse, mutect2, varscan2
- REG3G | c.447G>C p.L149= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as COSV55450843; called by muse, mutect2, varscan2
- RIMS4 | c.192C>T p.H64= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as rs778166180, COSV65720329; called by muse, mutect2, varscan2
- RIOX2 | c.243C>T p.F81= | Silent (SNP) | VAF 141/195 reads (72%) | catalogued as rs143209673; called by muse, mutect2, varscan2
- SCN5A | c.5646C>A p.A1882= (on ENST00000333535 / NM_198056.3; = p.A1881= on NM_000335.5) | Silent (SNP) | VAF 46/99 reads (46%) | catalogued as COSV61134217; called by muse, mutect2, varscan2
- SGO1 | c.987C>G p.V329= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs747292509, COSV99768522; called by muse, mutect2, varscan2
- SIPA1L2 | c.2796C>T p.I932= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV53390212, COSV53395766; called by muse, varscan2
- SIX4 | c.1935A>T p.A645= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV99382511; called by muse, mutect2, varscan2
- SOX3 | c.423G>T p.R141= | Silent (SNP) | VAF 23/35 reads (66%) | catalogued as COSV100983760; called by muse, mutect2, varscan2
- SPDEF | c.589C>T p.L197= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV65001355; called by muse, mutect2, varscan2
- SYNE3 | c.579C>G p.A193= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100516513; called by muse, mutect2, varscan2
- TAS2R41 | c.855C>T p.F285= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs750163018, COSV68765049; called by muse, mutect2, varscan2
- TEKT5 | c.1266C>T p.I422= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs753587144, COSV51590709; called by muse, mutect2
- THBS2 | c.1245C>T p.C415= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV64681091; called by muse, mutect2, varscan2
- TMEM131 | c.4125G>T p.S1375= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV51782453; called by muse, mutect2, varscan2
- TMEM200A | c.405T>A p.I135= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV51656698; called by muse, mutect2, varscan2
- TMPRSS11A | c.969C>T p.S323= | Silent (SNP) | VAF 37/149 reads (25%) | catalogued as COSV58360104; called by muse, mutect2, varscan2
- TRAPPC11 | c.3015G>T p.P1005= | Silent (SNP) | VAF 73/120 reads (61%) | catalogued as rs532244366, COSV58218111; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRAV10 | c.219C>T p.F73= | Silent (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- TRHDE | c.2577A>T p.T859= | Silent (SNP) | VAF 43/73 reads (59%) | catalogued as COSV53856773; called by muse, mutect2, varscan2
- TRPA1 | c.2670C>A p.I890= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV51564838; called by muse, mutect2, varscan2
- TRPV6 | c.1152C>A p.T384= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as COSV63892878; called by muse, mutect2, varscan2
- TSHZ2 | c.2439C>T p.S813= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs1351492700, COSV61590249; called by muse, mutect2, varscan2
- USH2A | c.7101G>T p.G2367= | Silent (SNP) | VAF 33/139 reads (24%) | catalogued as COSV100242803, COSV56366510; called by muse, mutect2, varscan2
- USP40 | c.1695A>G p.L565= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1559255886, COSV52485498; called by muse, mutect2, varscan2
- UTRN | c.1929G>T p.G643= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV62342538; called by muse, mutect2, varscan2
- VPS13B | c.10242C>T p.L3414= | Silent (SNP) | VAF 37/84 reads (44%) | catalogued as COSV62151512; called by muse, mutect2, varscan2
- WDR11 | c.1305A>T p.A435= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV54791086; called by muse, mutect2, varscan2
- WDR25 | c.1488G>T p.R496= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV58938639; called by muse, mutect2, varscan2
- WDR59 | c.433C>T p.L145= | Silent (SNP) | VAF 61/251 reads (24%) | catalogued as rs1396044252, COSV50940512; called by muse, mutect2, varscan2
- ZMYND8 | c.1404C>T p.F468= (on ENST00000311275 / NM_001363741.2; = p.F488= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs778893637, COSV53691402; called by muse, mutect2, varscan2
- ZNF207 | c.1164G>T p.R388= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as COSV100340696; called by muse, mutect2, varscan2
- ZP4 | c.1386C>T p.L462= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV63912933; called by muse, mutect2, varscan2
- ANKRD33 | c.-74C>A | 5'UTR (SNP) | VAF 33/54 reads (61%) | catalogued as COSV100001538; called by muse, mutect2, varscan2
- DCHS2 | n.7131G>T | RNA (SNP) | VAF 849/938 reads (91%) | catalogued as COSV61768654, COSV61777278; called by muse, mutect2, varscan2
- ILF3 | c.*264C>T | 3'UTR (SNP) | VAF 11/34 reads (32%) | catalogued as rs373656524; called by muse, mutect2, varscan2
- MICAL3 | c.2241+4659C>A | Intron (SNP) | VAF 20/60 reads (33%) | catalogued as COSV99262952; called by muse, mutect2, varscan2
- MIR1185-1 | n.71T>C | RNA (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- MIR485 | n.55G>T | RNA (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- MIR510 | n.43T>A | RNA (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- MORF4 | n.518C>A | RNA (SNP) | VAF 33/181 reads (18%) | called by muse, mutect2, varscan2
- POFUT1 | c.542+293G>A | Intron (SNP) | VAF 16/71 reads (23%) | catalogued as COSV100998404, COSV99058640; called by muse, mutect2, varscan2
- TUBB7P | n.545C>A | RNA (SNP) | VAF 38/90 reads (42%) | called by muse, varscan2
